FM case AD10674 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/748f24b1-276c-4d18-8150-7be5e55897a7

Female, 55.3 years: diagnosis not reported by GDC of the female genital tract; metastasis biopsied or resected from the vulva. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
